Gene-level copy-number profile of tumor specimen TCGA-VD-A8KD-01A from TCGA case TCGA-VD-A8KD, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IV; Age at diagnosis: 72.4 years (26,457 days).
Specimen TCGA-VD-A8KD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UVM.0439b6e9-7122-4284-88de-0db8c339c691.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VD-A8KD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS (sample pair TCGA-VD-A8KD-01A|TCGA-VD-A8KD-10B); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/84b8aa52-14c2-4ec5-a24a-3ed154b2cf73

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,330; copy number 2: 51,009; copy number 3: 1,220; copy number 4: 1,261.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VD-A8KD-01A-11D-A39V-01): tumor purity 0.83, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,909. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
